Somatic mutation profile of tumor specimen CDDP-ABJ3-TTP2-A (aliquot CDDP-ABJ3-TTP2-A-1-0-D-A500-36) from CDDP_EAGLE case CDDP-ABJ3, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 59 years.
Specimen CDDP-ABJ3-TTP2-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e972bc7-cab1-496a-bb37-1fa2d50f02d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ABJ3-NB1-A (Blood Derived Normal), aliquot CDDP-ABJ3-NB1-A-1-0-D-A500-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8c8feb3-5396-467c-afeb-bbf11701dbe4

The open-access MAF lists 523 somatic variants for this specimen: 358 protein-altering or splice-affecting, 106 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 320, Silent 106, Intron 29, Nonsense Mutation 20, 3'UTR 13, RNA 7, Frame Shift Del 7, Splice Site 5, 5'Flank 4, 3'Flank 4, Frame Shift Ins 3, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 42/281 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AATK | c.1418G>A p.R473Q (on ENST00000326724 / NM_001080395.3; = p.R370Q on NM_004920.2) | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as rs888195768; called by muse, mutect2
- ABCB5 | c.2626-2A>T p.X876_splice (on ENST00000404938 / NM_001163941.2; = p.X431_splice on NM_178559.6) | Splice Site (SNP) | VAF 15/72 reads (21%) | catalogued as COSV51702720, COSV99328320; called by muse, mutect2, varscan2
- ABCC1 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 23/327 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs771919617, COSV60679906; called by muse, mutect2
- ACVR2A | c.332A>T p.N111I | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54018549; called by muse, mutect2
- ADAM23 | c.728C>T p.T243I | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.216); catalogued as COSV52208344; called by muse, mutect2
- AFM | c.1339C>A p.L447M | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1356067732; called by muse, mutect2
- AKR1B15 | c.718C>A p.P240T | Missense Mutation (SNP) | VAF 32/329 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71152446; called by muse, mutect2
- BCHE | c.1241G>C p.R414P | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52262369, COSV52263017; called by muse, mutect2, varscan2
- BMPR2 | c.1472G>C p.R491P | Missense Mutation (SNP) | VAF 24/315 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM002240, COSV65808679; called by muse, mutect2
- BRINP3 | c.1250G>C p.G417A | Missense Mutation (SNP) | VAF 60/321 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100819281; called by muse, mutect2, varscan2
- CAVIN2 | c.1219G>T p.E407* | Nonsense Mutation (SNP) | VAF 18/196 reads (9%) | catalogued as COSV58425621; called by muse, mutect2
- CDH12 | c.2321G>T p.R774L | Missense Mutation (SNP) | VAF 54/369 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.539); catalogued as COSV66401295; called by muse, mutect2, varscan2
- CDH6 | c.2298C>G p.Y766* | Nonsense Mutation (SNP) | VAF 62/409 reads (15%) | catalogued as COSV54066790; called by muse, mutect2, varscan2
- CLCN1 | c.2692G>T p.G898W | Missense Mutation (SNP) | VAF 51/456 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV100578257; called by muse, mutect2, varscan2
- CNOT1 | c.5756A>G p.H1919R | Missense Mutation (SNP) | VAF 70/450 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.119); catalogued as rs761938101; called by muse, mutect2, varscan2
- COL28A1 | c.520A>G p.I174V | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.94); PolyPhen benign (0.031); catalogued as rs190228452; called by muse, mutect2, varscan2
- COL4A2 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1317141175, COSV64629041; called by muse, mutect2
- CSMD3 | c.7856C>A p.A2619E (on ENST00000297405 / NM_001363185.1; = p.A2515E on NM_052900.3) | Missense Mutation (SNP) | VAF 42/294 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.142); catalogued as rs1161612497; called by muse, mutect2, varscan2
- DMD | c.3257A>T p.K1086M | Missense Mutation (SNP) | VAF 32/272 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as CD071314; called by muse, mutect2, varscan2
- DMD | c.9G>T p.W3C | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as CM031161; called by muse, varscan2
- DRD5 | c.1339G>A p.G447S | Missense Mutation (SNP) | VAF 31/248 reads (13%) | SIFT tolerated (0.85); PolyPhen benign (0.057); catalogued as rs748536594; called by muse, varscan2
- DYSF | c.5429G>T p.R1810M | Missense Mutation (SNP) | VAF 24/388 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as CS075116, CS106043; called by muse, mutect2
- EDN1 | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 46/247 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65080760; called by muse, mutect2, varscan2
- FCER1A | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1433078324, COSV100929236, COSV63668193; called by muse, varscan2
- FCN1 | c.20C>A p.T7N | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV65662367; called by muse, mutect2, varscan2
- FLG | c.8270C>A p.P2757H | Missense Mutation (SNP) | VAF 94/1133 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as rs759879208, COSV64241854; called by muse, mutect2
- FSCB | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 17/524 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV61217395; called by muse, mutect2
- GDF10 | c.586C>A p.P196T | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.424); catalogued as rs1555207484; called by muse, mutect2, varscan2
- GH2 | c.538G>T p.D180Y | Missense Mutation (SNP) | VAF 131/788 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs759902714; called by muse, mutect2, varscan2
- GNAS | c.248del p.P83Rfs*607 | Frame Shift Del (DEL) | VAF 84/597 reads (14%) | catalogued as COSV58335388; called by mutect2, pindel, varscan2
- GP5 | c.44G>T p.R15L | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.237); catalogued as COSV55465514; called by muse, mutect2
- GREM2 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 58/384 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.442); catalogued as rs765293721, COSV58950168; called by muse, mutect2, varscan2
- GREM2 | c.249C>A p.S83R | Missense Mutation (SNP) | VAF 55/382 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.018); catalogued as COSV58950057; called by muse, mutect2, varscan2
- GRM7 | c.154G>T p.G52W | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63140513; called by muse, mutect2, varscan2
- HAO1 | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 28/240 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs375983921; called by muse, mutect2, varscan2
- HAVCR2 | c.329G>T p.C110F | Missense Mutation (SNP) | VAF 29/314 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104410900; called by muse, mutect2
- HPSE2 | c.770G>T p.W257L | Missense Mutation (SNP) | VAF 44/277 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65183582; called by muse, mutect2, varscan2
- HUNK | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 36/193 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as COSV99528452; called by muse, mutect2, varscan2
- IGHV1-45 | c.223G>A p.G75S | Missense Mutation (SNP) | VAF 38/420 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.257); catalogued as rs868975561; called by muse, mutect2
- IGKV1-6 | c.297C>A p.S99R | Missense Mutation (SNP) | VAF 38/498 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as rs746073147; called by muse, mutect2
- IGSF21 | c.1169C>A p.A390D | Missense Mutation (SNP) | VAF 27/212 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.162); catalogued as COSV52125877, COSV52134646, COSV52147493; called by muse, mutect2, varscan2
- KCNH7 | c.250C>A p.Q84K | Missense Mutation (SNP) | VAF 26/369 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.17); catalogued as COSV100036190; called by muse, mutect2
- KCNQ3 | c.802G>C p.G268R | Missense Mutation (SNP) | VAF 100/704 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66463190; called by muse, mutect2, varscan2
- KPRP | c.1193G>T p.R398L | Missense Mutation (SNP) | VAF 80/443 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV64222829; called by muse, mutect2, varscan2
- KRTAP12-4 | c.276C>A p.C92* | Nonsense Mutation (SNP) | VAF 68/422 reads (16%) | catalogued as COSV100552821; called by muse, mutect2, varscan2
- LGALS9 | c.822G>T p.E274D (on ENST00000395473 / NM_009587.3; = p.E242D on NM_002308.4) | Missense Mutation (SNP) | VAF 72/453 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.473); catalogued as COSV100119417; called by mutect2, varscan2
- LRFN2 | c.268C>A p.H90N | Missense Mutation (SNP) | VAF 37/286 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV100599267; called by muse, mutect2, varscan2
- LRRN3 | c.1405C>A p.L469M | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV57823335; called by muse, mutect2, varscan2
- LTBP2 | c.1705G>C p.E569Q | Missense Mutation (SNP) | VAF 24/338 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.502); catalogued as rs1178267569, COSV56204540; called by muse, mutect2
- MAP4K4 | c.3053G>T p.G1018V (on ENST00000347699 / NM_001242559.2; = p.G936V on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV56334124; called by muse, mutect2
- MEGF10 | c.441C>A p.H147Q | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.987); catalogued as COSV57257864; called by muse, mutect2, varscan2
- MIA2 | c.2149C>T p.P717S | Missense Mutation (SNP) | VAF 701/1257 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1804860; called by muse, mutect2, varscan2
- MUC16 | c.27140G>C p.S9047T | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.065); catalogued as COSV67466698; called by muse, mutect2, varscan2
- MXRA5 | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs1248091216; called by muse, mutect2, varscan2
- NBPF12 | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 117/599 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV58775688, COSV58777765; called by muse, mutect2, varscan2
- NPHP4 | c.2492C>T p.P831L | Missense Mutation (SNP) | VAF 56/223 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs568060648, COSV100977065; called by muse, mutect2, varscan2
- NPSR1 | c.660C>A p.F220L | Missense Mutation (SNP) | VAF 36/372 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.349); catalogued as COSV62202224; called by muse, mutect2
- NSD2 | c.2966C>T p.P989L | Missense Mutation (SNP) | VAF 47/242 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1286095958; called by muse, mutect2, varscan2
- NTF3 | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV58417361; called by muse, mutect2
- OR10T2 | c.848C>A p.P283H | Missense Mutation (SNP) | VAF 41/234 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758256313; called by muse, mutect2, varscan2
- OR11H7 | c.873C>A p.S291R | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as rs1173624192; called by muse, mutect2, varscan2
- OR1J2 | c.826C>G p.L276V | Missense Mutation (SNP) | VAF 64/300 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.009); catalogued as rs763414142; called by muse, mutect2, varscan2
- OR2T10 | c.232G>C p.V78L | Missense Mutation (SNP) | VAF 28/468 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV57898389; called by muse, mutect2
- OR4M1 | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 71/366 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as rs1405180671, COSV60062819; called by muse, mutect2, varscan2
- OR8J3 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100040671, COSV56882319; called by muse, mutect2, varscan2
- PAPPA2 | c.2351G>C p.R784P | Missense Mutation (SNP) | VAF 22/253 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.889); catalogued as COSV62783224; called by muse, mutect2
- PCDHA6 | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 16/391 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.292); catalogued as COSV65352521; called by muse, mutect2
- PCDHA6 | c.1779G>T p.K593N | Missense Mutation (SNP) | VAF 97/680 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs782569714; called by muse, mutect2, varscan2
- PCDHGA3 | c.1640C>A p.S547* | Nonsense Mutation (SNP) | VAF 118/573 reads (21%) | catalogued as COSV53986325; called by muse, mutect2, varscan2
- PCLO | c.4396G>T p.E1466* | Nonsense Mutation (SNP) | VAF 10/103 reads (10%) | catalogued as COSV61633695; called by muse, mutect2
- PDZD2 | c.1324G>T p.D442Y | Missense Mutation (SNP) | VAF 44/240 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1371139765; called by muse, mutect2, varscan2
- PEG3 | c.2246C>A p.A749E | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV55633501, COSV99688824; called by muse, mutect2, varscan2
- PKP1 | c.2008G>T p.A670S | Missense Mutation (SNP) | VAF 50/305 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV104380579; called by muse, mutect2, varscan2
- PKP2 | c.681C>A p.S227R | Missense Mutation (SNP) | VAF 49/550 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.065); catalogued as COSV99297949; called by muse, mutect2
- PMVK | c.385G>T p.V129F | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV100870491; called by muse, mutect2, varscan2
- PRAC1 | c.9C>A p.C3* | Nonsense Mutation (SNP) | VAF 30/277 reads (11%) | catalogued as rs1446171363, COSV51704882, COSV99284881; called by muse, mutect2, varscan2
- PRDM1 | c.1135G>T p.A379S | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.04); catalogued as rs748814652; called by muse, mutect2, varscan2
- PRDM14 | c.1376G>T p.R459L | Missense Mutation (SNP) | VAF 91/377 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52575075; called by muse, mutect2, varscan2
- PTDSS1 | c.1378C>T p.R460W | Missense Mutation (SNP) | VAF 76/452 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV61264122; called by muse, mutect2, varscan2
- PTPN5 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 51/409 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1037962955, COSV62125787; called by muse, mutect2, varscan2
- PTPRN | c.2651C>A p.T884K | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1023841205, COSV55345237, COSV55350941; called by muse, mutect2, varscan2
- PTPRT | c.4247A>T p.N1416I | Missense Mutation (SNP) | VAF 42/269 reads (16%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.999); catalogued as COSV61971453, COSV62003032; called by muse, mutect2, varscan2
- RASA1 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 24/518 reads (5%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.01); catalogued as rs1290733136; called by muse, mutect2
- RASGRF1 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 46/365 reads (13%) | catalogued as rs971091880, COSV101369759; called by muse, mutect2, varscan2
- RXRA | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 61/259 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as COSV100709197; called by muse, mutect2, varscan2
- SAMSN1 | c.609G>C p.W203C | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53477905, COSV99581716; called by muse, mutect2, varscan2
- SDK1 | c.3803G>T p.R1268L | Missense Mutation (SNP) | VAF 26/444 reads (6%) | SIFT tolerated (0.8); PolyPhen benign (0.005); catalogued as COSV67371383; called by muse, mutect2
- SEL1L | c.478A>T p.K160* | Nonsense Mutation (SNP) | VAF 7/129 reads (5%) | catalogued as COSV100377642; called by muse, mutect2
- SEMA3F | c.1152C>A p.N384K | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.898); catalogued as rs767470094; called by muse, mutect2, varscan2
- SGPP2 | c.1102G>T p.E368* | Nonsense Mutation (SNP) | VAF 27/329 reads (8%) | catalogued as COSV58331626; called by muse, mutect2
- SIGLEC10 | c.1676C>A p.T559K | Missense Mutation (SNP) | VAF 25/404 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV59480418; called by muse, mutect2
- SLC17A7 | c.151G>C p.V51L | Missense Mutation (SNP) | VAF 42/575 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1163997597; called by muse, mutect2
- SLC27A5 | c.2012C>T p.S671F | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as rs759648189; called by muse, mutect2, varscan2
- SLC7A14 | c.1174G>T p.G392W | Missense Mutation (SNP) | VAF 43/238 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51579651; called by muse, mutect2, varscan2
- SLCO4C1 | c.1868G>A p.R623Q | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs780417654, COSV60516140; called by muse, mutect2, varscan2
- SPEF2 | c.4027G>A p.E1343K | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV100608018; called by muse, mutect2
- SSC5D | c.649G>T p.G217W | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52700210; called by muse, mutect2, varscan2
- STARD8 | c.387C>A p.F129L | Missense Mutation (SNP) | VAF 42/239 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs1446867671; called by muse, mutect2, varscan2
- SUGP1 | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 44/240 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs1184108411; called by muse, mutect2, varscan2
- SYCP2L | c.593G>C p.R198P | Missense Mutation (SNP) | VAF 11/185 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.884); catalogued as COSV99305109; called by muse, mutect2
- TBX20 | c.932G>T p.R311L | Missense Mutation (SNP) | VAF 166/596 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV68786032; called by muse, mutect2, varscan2
- TG | c.6571C>G p.L2191V | Missense Mutation (SNP) | VAF 77/380 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.074); catalogued as rs759430007; called by muse, mutect2, varscan2
- THOC5 | c.759G>T p.Q253H | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV63798651, COSV63798735; called by muse, mutect2
- TNN | c.3458G>T p.G1153V | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs1422749087; called by muse, mutect2
- TRPV5 | c.86G>T p.W29L | Missense Mutation (SNP) | VAF 14/181 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV54688870; called by muse, mutect2
- TTN | c.53998G>T p.V18000F (on ENST00000591111; = p.V10576F on NM_003319.4) | Missense Mutation (SNP) | VAF 10/122 reads (8%) | PolyPhen benign (0.04); catalogued as rs1432149283; called by muse, mutect2
- UBQLN3 | c.1547C>A p.A516E | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV61164034; called by muse, mutect2
- YWHAQ | c.15G>T p.E5D | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as rs761020810; called by muse, mutect2
- ZDHHC3 | c.405C>G p.I135M | Missense Mutation (SNP) | VAF 25/289 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV56101842; called by muse, mutect2
- ZFR2 | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); catalogued as rs757720623; called by muse, mutect2, varscan2
- ZFYVE28 | c.416G>T p.R139L | Missense Mutation (SNP) | VAF 30/342 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs139959101, COSV52114613; called by muse, mutect2
- ZNF207 | c.803C>G p.S268* | Nonsense Mutation (SNP) | VAF 11/104 reads (11%) | catalogued as COSV58301463; called by muse, mutect2, varscan2
- ZNF276 | c.533G>T p.G178V (on ENST00000443381 / NM_001113525.2; = p.G103V on NM_152287.4) | Missense Mutation (SNP) | VAF 61/346 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99234667; called by muse, mutect2, varscan2
- ZNF716 | c.1397G>T p.C466F | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV70781529; called by muse, mutect2, varscan2
- ZSWIM8 | c.4960C>G p.Q1654E (on ENST00000605216 / NM_001242487.2; = p.Q1659E on NM_015037.3) | Missense Mutation (SNP) | VAF 19/375 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as rs1274858109; called by muse, mutect2
- AARSD1 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 50/279 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- ACE | c.2672T>C p.I891T | Missense Mutation (SNP) | VAF 40/516 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ACTG2 | c.323A>C p.E108A | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ADA | c.96G>T p.R32S | Missense Mutation (SNP) | VAF 52/268 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.294); called by muse, mutect2
- ADAMTS6 | c.2687C>A p.T896N | Missense Mutation (SNP) | VAF 12/177 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.826); called by muse, mutect2
- ADAMTS7 | c.245A>G p.Y82C | Missense Mutation (SNP) | VAF 35/245 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADGRB3 | c.3544G>T p.A1182S | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- AKAP9 | c.2076G>T p.Q692H | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ANK2 | c.2611G>A p.G871S | Missense Mutation (SNP) | VAF 79/462 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- ANKUB1 | c.1226C>A p.P409Q | Missense Mutation (SNP) | VAF 47/308 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ANKUB1 | c.1225C>A p.P409T | Missense Mutation (SNP) | VAF 46/305 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- APAF1 | c.3110G>T p.C1037F (on ENST00000551964 / NM_181861.2; = p.C983F on NM_001160.3) | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2
- APOE | c.815C>A p.A272D | Missense Mutation (SNP) | VAF 44/552 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- ARHGAP26 | c.384G>C p.K128N | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- ARHGEF12 | c.538G>A p.G180R | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- ARMCX4 | c.167-1G>T p.X56_splice | Splice Site (SNP) | VAF 9/45 reads (20%) | called by muse, varscan2
- ARSI | c.1165C>A p.L389M | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ART4 | c.678T>A p.F226L | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- ATG9A | c.2115G>C p.E705D | Missense Mutation (SNP) | VAF 15/197 reads (8%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.935); called by muse, mutect2
- ATP6V1G3 | c.12G>T p.Q4H | Missense Mutation (SNP) | VAF 38/384 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATRN | c.3805G>A p.A1269T | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- ATXN7L1 | c.1054G>C p.E352Q | Missense Mutation (SNP) | VAF 23/364 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0.145); called by muse, mutect2
- BAG1 | c.990C>G p.C330W | Missense Mutation (SNP) | VAF 63/439 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- BCL6 | c.1730A>T p.N577I | Missense Mutation (SNP) | VAF 56/292 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- BCOR | c.1145A>T p.E382V | Missense Mutation (SNP) | VAF 36/415 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); called by muse, mutect2
- BEST2 | c.901G>C p.D301H | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- BRINP3 | c.138G>C p.W46C | Missense Mutation (SNP) | VAF 57/392 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- C10orf71 | c.2241G>T p.W747C | Missense Mutation (SNP) | VAF 45/301 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CAMSAP2 | c.1522G>T p.D508Y (on ENST00000236925 / NM_001297707.2; = p.D497Y on NM_203459.3) | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- CCAR1 | c.209A>T p.Q70L | Missense Mutation (SNP) | VAF 45/231 reads (19%) | SIFT tolerated, low confidence (0.35); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- CCDC33 | c.789G>C p.Q263H | Missense Mutation (SNP) | VAF 53/327 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- CDH6 | c.2010G>T p.Q670H | Missense Mutation (SNP) | VAF 64/555 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CFAP46 | c.7189G>T p.G2397C | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- CFH | c.449C>A p.T150K | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CHML | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 21/210 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- CMTR2 | c.707G>T p.G236V | Missense Mutation (SNP) | VAF 26/197 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CMTR2 | c.706G>T p.G236W | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL12A1 | c.6996G>T p.W2332C | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL14A1 | c.1985A>T p.Y662F | Missense Mutation (SNP) | VAF 77/274 reads (28%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- COL14A1 | c.2095G>C p.D699H | Missense Mutation (SNP) | VAF 67/347 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL22A1 | c.1486G>T p.G496C | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CR1 | c.92T>A p.V31E | Missense Mutation (SNP) | VAF 53/286 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CSMD2 | c.10054G>C p.D3352H | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CSMD3 | c.6338G>T p.G2113V (on ENST00000297405 / NM_001363185.1; = p.G2009V on NM_052900.3) | Missense Mutation (SNP) | VAF 49/405 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CSNK1G2 | c.659G>T p.S220I | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CST9 | c.64C>G p.Q22E | Missense Mutation (SNP) | VAF 22/344 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.258); called by muse, mutect2
- CUX2 | c.2135T>A p.L712Q | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); called by muse, varscan2
- DAAM1 | c.183+1G>T p.X61_splice | Splice Site (SNP) | VAF 38/450 reads (8%) | called by muse, mutect2
- DCHS1 | c.8662G>T p.G2888C | Missense Mutation (SNP) | VAF 30/332 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2
- DCHS1 | c.4310C>A p.A1437E | Missense Mutation (SNP) | VAF 21/262 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.065); called by muse, mutect2
- DDX60 | c.4977G>C p.R1659S | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.122); called by muse, mutect2
- DEFB116 | c.148G>C p.A50P | Missense Mutation (SNP) | VAF 27/208 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- DEK | c.602G>T p.S201I | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- DEUP1 | c.641A>T p.D214V | Missense Mutation (SNP) | VAF 34/159 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- DHX34 | c.554G>A p.G185D | Missense Mutation (SNP) | VAF 46/264 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DMBT1 | c.2429G>T p.W810L | Missense Mutation (SNP) | VAF 65/646 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DMD | c.10T>G p.W4G | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.592); called by muse, varscan2
- DNAH11 | c.6223G>T p.V2075F | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DOCK3 | c.4712_4713insCA p.K1571Nfs*28 | Frame Shift Ins (INS) | VAF 44/316 reads (14%) | called by mutect2, pindel, varscan2
- DRP2 | c.2185G>A p.A729T | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- DSC1 | c.1614A>T p.K538N | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- DYSF | c.4597C>A p.Q1533K | Missense Mutation (SNP) | VAF 86/592 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- EIF2B5 | c.1180+3G>A | Splice Region (SNP) | VAF 25/336 reads (7%) | called by muse, mutect2
- ELMO1 | c.2036G>A p.S679N | Missense Mutation (SNP) | VAF 58/525 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ELN | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 65/535 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERICH6 | c.666+1G>A p.X222_splice | Splice Site (SNP) | VAF 18/111 reads (16%) | called by muse, mutect2, varscan2
- ERN2 | c.1832dup p.L612Sfs*38 | Frame Shift Ins (INS) | VAF 47/411 reads (11%) | called by mutect2, pindel, varscan2
- ERVV-2 | c.803A>T p.D268V | Missense Mutation (SNP) | VAF 42/654 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.088); called by muse, mutect2
- ESRRA | c.747C>G p.F249L | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EXOC3L2 | c.1607G>T p.R536L | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.704); called by muse, mutect2
- EYS | c.6299C>A p.P2100H | Missense Mutation (SNP) | VAF 44/270 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- FAM32A | c.109C>G p.L37V | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.028); called by muse, mutect2
- FAM71E2 | c.166G>T p.G56C | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FAM81B | c.196C>A p.L66I | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- FARP2 | c.1331G>T p.R444M | Missense Mutation (SNP) | VAF 36/281 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- FAT4 | c.11690G>T p.R3897M | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.992); called by muse, mutect2
- FHL1 | c.-241C>A | Splice Region (SNP) | VAF 62/325 reads (19%) | called by muse, mutect2, varscan2
- FMN2 | c.448G>T p.A150S | Missense Mutation (SNP) | VAF 31/341 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.376); called by muse, mutect2
- FMO2 | c.244C>A p.L82M | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (1); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FRAS1 | c.1597G>C p.D533H | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- FRY | c.7462C>G p.L2488V | Missense Mutation (SNP) | VAF 17/501 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2
- G6PC | c.917T>A p.L306Q | Missense Mutation (SNP) | VAF 87/500 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GAB1 | c.1885G>T p.D629Y | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GABPA | c.442G>T p.G148C | Missense Mutation (SNP) | VAF 43/308 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- GABRG2 | c.969C>A p.C323* (on ENST00000361925 / NM_001375343.1; = p.C283* on NM_000816.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 18/326 reads (6%) | called by muse, mutect2
- GAK | c.227A>T p.E76V | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- GALNT6 | c.937C>G p.Q313E | Missense Mutation (SNP) | VAF 40/514 reads (8%) | SIFT tolerated (0.87); PolyPhen benign (0.122); called by muse, mutect2
- GCC1 | c.1885G>C p.D629H | Missense Mutation (SNP) | VAF 30/226 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- GCKR | c.1840G>A p.A614T | Missense Mutation (SNP) | VAF 44/474 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.028); called by muse, mutect2
- GGT5 | c.798G>C p.E266D | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.491); called by muse, mutect2
- GIMAP7 | c.491G>T p.C164F | Missense Mutation (SNP) | VAF 111/572 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- GLRA1 | c.337C>G p.L113V | Missense Mutation (SNP) | VAF 82/648 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- GMIP | c.103G>T p.V35L | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- GPRIN1 | c.2342C>A p.A781D | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GRK7 | c.1540C>A p.P514T | Missense Mutation (SNP) | VAF 48/316 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- GRM5 | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 109/355 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM8 | c.2320C>G p.P774A | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GTF2F1 | c.830G>T p.G277V | Missense Mutation (SNP) | VAF 60/276 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.067); called by muse, varscan2
- H3C12 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 43/236 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- HEPACAM2 | c.560G>A p.R187K (on ENST00000394468 / NM_001039372.4; = p.R175K on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 108/570 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HIVEP1 | c.1624A>T p.I542L | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HLX | c.1058G>T p.G353V | Missense Mutation (SNP) | VAF 37/229 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- HTR4 | c.272T>A p.V91E | Missense Mutation (SNP) | VAF 75/546 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGF2BP3 | c.334C>A p.Q112K | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ILK | c.1187C>G p.S396C | Missense Mutation (SNP) | VAF 36/460 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- ILVBL | c.1613A>T p.K538M | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- IQCA1 | c.1452G>C p.K484N | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.216); called by muse, mutect2
- IRX1 | c.1424C>A p.A475E | Missense Mutation (SNP) | VAF 45/366 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- ITGA1 | c.416G>T p.G139V | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITPR1 | c.3265A>C p.S1089R (on ENST00000354582; = p.S1074R on NM_002222.7) | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ITPRID1 | c.125C>A p.P42H | Missense Mutation (SNP) | VAF 23/196 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- ITPRID1 | c.1513G>T p.E505* | Nonsense Mutation (SNP) | VAF 102/358 reads (28%) | called by muse, mutect2, varscan2
- JAG2 | c.3415G>C p.E1139Q | Missense Mutation (SNP) | VAF 27/199 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- KAT7 | c.1520C>T p.P507L | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNA4 | c.1722G>C p.E574D | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- KCNK7 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 60/209 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- KDSR | c.794G>T p.S265I | Missense Mutation (SNP) | VAF 20/223 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2
- KHDC4 | c.1537G>T p.E513* | Nonsense Mutation (SNP) | VAF 56/231 reads (24%) | called by muse, varscan2
- KLHL12 | c.749A>T p.D250V | Missense Mutation (SNP) | VAF 32/235 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KLK8 | c.155A>T p.Q52L | Missense Mutation (SNP) | VAF 47/304 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- KMT5B | c.721A>G p.M241V | Missense Mutation (SNP) | VAF 68/241 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- KRTAP10-3 | c.500G>T p.R167M | Missense Mutation (SNP) | VAF 59/394 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- KRTAP12-4 | c.277C>A p.Q93K | Missense Mutation (SNP) | VAF 68/419 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- KRTAP5-4 | c.686G>C p.*229Sext*53 | Nonstop Mutation (SNP) | VAF 38/232 reads (16%) | called by muse, mutect2
- LAMA2 | c.6758C>A p.A2253D | Missense Mutation (SNP) | VAF 64/436 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMA5 | c.4539G>T p.Q1513H | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- LAMB1 | c.2450G>T p.G817V | Missense Mutation (SNP) | VAF 79/598 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LPA | c.2494C>G p.Q832E | Missense Mutation (SNP) | VAF 54/566 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP12 | c.2305G>T p.D769Y | Missense Mutation (SNP) | VAF 34/330 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- LRRK1 | c.1281G>C p.L427F | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LSG1 | c.582+1del p.X194_splice | Splice Site (DEL) | VAF 22/159 reads (14%) | called by mutect2, pindel*, varscan2
- LTK | c.1064C>A p.P355H | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAP1B | c.6218C>T p.P2073L | Missense Mutation (SNP) | VAF 40/370 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MATN1 | c.1390G>T p.V464L | Missense Mutation (SNP) | VAF 32/262 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MEGF6 | c.68T>A p.L23H | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.869); called by muse, mutect2
- MGARP | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 12/147 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MTA1 | c.1423A>T p.T475S | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.245); called by muse, mutect2
- MYH8 | c.4893G>T p.Q1631H | Missense Mutation (SNP) | VAF 52/321 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- MYO18B | c.4831C>A p.L1611M | Missense Mutation (SNP) | VAF 17/222 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0.02); called by muse, mutect2
- MYOM2 | c.2891A>T p.H964L | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- NBAS | c.1188G>T p.W396C | Missense Mutation (SNP) | VAF 34/222 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NDRG1 | c.25G>T p.D9Y | Missense Mutation (SNP) | VAF 69/481 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- NIPAL2 | c.653T>C p.L218P | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- NME8 | c.1504G>A p.G502R | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- NOSTRIN | c.1495G>T p.A499S (on ENST00000317647 / NM_001039724.4; = p.A421S on NM_052946.3) | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.009); called by muse, mutect2
- NOTCH3 | c.1595G>T p.R532L | Missense Mutation (SNP) | VAF 35/455 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.341); called by muse, mutect2
- NOX3 | c.1569C>A p.Y523* | Nonsense Mutation (SNP) | VAF 41/234 reads (18%) | called by muse, mutect2, varscan2
- NR1H4 | c.170C>G p.S57W (on ENST00000551379 / NM_001206993.2; = p.S47W on NM_005123.4) | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); called by muse, mutect2
- NR1H4 | c.530G>T p.G177V (on ENST00000551379 / NM_001206993.2; = p.G167V on NM_005123.4) | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NRROS | c.538C>G p.L180V | Missense Mutation (SNP) | VAF 48/314 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NTRK3 | c.2198C>T p.P733L (on ENST00000360948 / NM_001012338.2; = p.P719L on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/395 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUP210L | c.1472dup p.G492Wfs*11 | Frame Shift Ins (INS) | VAF 37/231 reads (16%) | called by mutect2, pindel
- OCRL | c.2194del p.L732Ffs*10 | Frame Shift Del (DEL) | VAF 35/226 reads (15%) | called by mutect2, pindel, varscan2
- OR2G6 | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 42/273 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- OR51E1 | c.244C>A p.P82T | Missense Mutation (SNP) | VAF 63/315 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR52E8 | c.387C>A p.Y129* | Nonsense Mutation (SNP) | VAF 52/230 reads (23%) | called by muse, mutect2, varscan2
- OR5A1 | c.179C>A p.T60K | Missense Mutation (SNP) | VAF 34/371 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.367); called by muse, mutect2
- OR7G3 | c.467C>A p.A156D | Missense Mutation (SNP) | VAF 18/373 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2
- PCARE | c.3453G>T p.E1151D | Missense Mutation (SNP) | VAF 63/410 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- PCDH11X | c.2030C>T p.P677L | Missense Mutation (SNP) | VAF 45/374 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- PCDHB3 | c.1240A>G p.R414G | Missense Mutation (SNP) | VAF 54/325 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- PCDHGA6 | c.2236G>T p.V746F | Missense Mutation (SNP) | VAF 78/528 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- PCDHGC4 | c.2036C>A p.S679Y | Missense Mutation (SNP) | VAF 12/315 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PCED1A | c.47G>T p.S16I | Missense Mutation (SNP) | VAF 13/208 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- PCTP | c.485A>T p.E162V | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- PERM1 | c.2125C>A p.L709I | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- PIGQ | c.1715A>G p.H572R | Missense Mutation (SNP) | VAF 29/278 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLEKHA8 | c.1188G>T p.Q396H | Missense Mutation (SNP) | VAF 85/254 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- PNLDC1 | c.1240G>C p.D414H | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- POLD3 | c.677A>G p.N226S | Missense Mutation (SNP) | VAF 54/192 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- POSTN | c.781G>T p.E261* | Nonsense Mutation (SNP) | VAF 19/143 reads (13%) | called by muse, mutect2, varscan2
- POU3F4 | c.701G>T p.R234M | Missense Mutation (SNP) | VAF 53/363 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP1R2B | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 110/646 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- PRAMEF1 | c.98G>T p.R33M | Missense Mutation (SNP) | VAF 75/518 reads (14%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- PRAMEF18 | c.858G>T p.Q286H | Missense Mutation (SNP) | VAF 18/593 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2
- PRDM9 | c.228C>A p.H76Q | Missense Mutation (SNP) | VAF 84/673 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.5); called by muse, varscan2
- PRMT1 | c.104A>T p.Q35L | Missense Mutation (SNP) | VAF 29/332 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- PRR12 | c.732C>G p.C244W (on ENST00000615927; = p.C1065W on NM_020719.3) | Missense Mutation (SNP) | VAF 66/475 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PRR36 | c.691G>T p.G231C | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated, low confidence (0.12); called by muse, mutect2
- PRRG3 | c.146T>A p.V49E | Missense Mutation (SNP) | VAF 48/298 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PSMD14 | c.669G>T p.K223N | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.049); called by muse, mutect2
- PTK2 | c.2638G>A p.G880R | Missense Mutation (SNP) | VAF 159/620 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- RAB4A | c.212G>C p.G71A | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- RALYL | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 53/201 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- RANBP2 | c.216G>T p.L72F | Missense Mutation (SNP) | VAF 40/258 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.057); called by mutect2, varscan2
- RANBP2 | c.217G>T p.E73* | Nonsense Mutation (SNP) | VAF 40/280 reads (14%) | called by muse, mutect2, varscan2
- RASGRP4 | c.926A>T p.H309L | Missense Mutation (SNP) | VAF 40/269 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- REXO2 | c.433C>T p.H145Y | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- RGPD4 | c.3214G>C p.A1072P | Missense Mutation (SNP) | VAF 40/491 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- RIPPLY3 | c.376C>A p.P126T | Missense Mutation (SNP) | VAF 30/347 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.037); called by muse, mutect2
- RNF130 | c.23G>C p.G8A | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF213 | c.1297G>T p.V433F | Missense Mutation (SNP) | VAF 61/372 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- ROBO4 | c.2087G>T p.R696L | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ROCK2 | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RP1L1 | c.6100G>T p.A2034S | Missense Mutation (SNP) | VAF 38/398 reads (10%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.02); called by muse, mutect2
- RPIA | c.338del p.Q113Rfs*3 | Frame Shift Del (DEL) | VAF 69/546 reads (13%) | called by mutect2, pindel, varscan2
- RSAD2 | c.841G>T p.E281* | Nonsense Mutation (SNP) | VAF 28/206 reads (14%) | called by muse, mutect2, varscan2
- RTL1 | c.3979A>T p.R1327W | Missense Mutation (SNP) | VAF 39/373 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- SATB2 | c.1656G>C p.R552S | Missense Mutation (SNP) | VAF 30/448 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SEMA6A | c.2100C>A p.S700R | Missense Mutation (SNP) | VAF 67/250 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- SETBP1 | c.1669G>T p.E557* | Nonsense Mutation (SNP) | VAF 27/281 reads (10%) | called by muse, mutect2
- SETX | c.4011A>T p.R1337S | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SIGLEC1 | c.1208del p.P403Lfs*5 | Frame Shift Del (DEL) | VAF 41/316 reads (13%) | called by mutect2, pindel, varscan2
- SLC20A1 | c.557A>G p.H186R | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC25A13 | c.1737G>T p.W579C | Missense Mutation (SNP) | VAF 90/655 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLC28A1 | c.742G>T p.G248C | Missense Mutation (SNP) | VAF 94/624 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SLFNL1 | c.346C>G p.L116V | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SP140 | c.395G>T p.S132I | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- SPON2 | c.194C>A p.P65H | Missense Mutation (SNP) | VAF 58/407 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STK36 | c.514G>T p.V172L | Missense Mutation (SNP) | VAF 38/352 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- SUSD5 | c.269G>T p.W90L | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TG | c.4666del p.T1556Qfs*11 | Frame Shift Del (DEL) | VAF 59/265 reads (22%) | called by mutect2, pindel, varscan2
- THBD | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2
- TIAM1 | c.4397G>T p.S1466I | Missense Mutation (SNP) | VAF 39/284 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- TLN1 | c.7306G>A p.A2436T | Missense Mutation (SNP) | VAF 52/331 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TMEM177 | c.436T>A p.S146T | Missense Mutation (SNP) | VAF 83/295 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- TMEM255B | c.356T>A p.L119H | Missense Mutation (SNP) | VAF 44/252 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- TMTC2 | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 22/362 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.272); called by muse, mutect2
- TRAK1 | c.36G>T p.R12S | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRAPPC10 | c.1576G>T p.A526S | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TRIM60 | c.592C>A p.Q198K | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- TRIM77 | c.1184T>A p.L395Q | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- TRIOBP | c.888A>T p.Q296H | Missense Mutation (SNP) | VAF 53/522 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRO | c.2892C>A p.S964R | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- UNC79 | c.5202G>T p.E1734D (on ENST00000393151 / NM_001346218.2; = p.E1557D on NM_020818.5) | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UPK1A | c.563C>A p.P188Q | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- USH2A | c.15291C>A p.N5097K | Missense Mutation (SNP) | VAF 48/356 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- USP38 | c.2758A>T p.R920* | Nonsense Mutation (SNP) | VAF 9/128 reads (7%) | called by muse, mutect2
- VCAN | c.6709C>G p.P2237A | Missense Mutation (SNP) | VAF 54/215 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.194); called by muse, mutect2
- VPS45 | c.950A>G p.N317S | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- WDR44 | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- WFIKKN2 | c.849del p.I284Sfs*13 | Frame Shift Del (DEL) | VAF 68/474 reads (14%) | called by mutect2, pindel, varscan2
- ZC3H6 | c.280_281delinsT p.S94Ffs*28 | Frame Shift Del (DEL) | VAF 8/74 reads (11%) | called by pindel, varscan2*
- ZNF148 | c.1123G>C p.G375R | Missense Mutation (SNP) | VAF 47/258 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ZNF180 | c.2041G>T p.A681S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.084); called by mutect2, varscan2
- ZNF250 | c.1347G>T p.K449N | Missense Mutation (SNP) | VAF 116/448 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- ZNF256 | c.1712G>T p.G571V | Missense Mutation (SNP) | VAF 54/323 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ZNF606 | c.1969T>C p.C657R | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF665 | c.1436G>A p.C479Y (on ENST00000600412; = p.C544Y on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF80 | c.290G>T p.R97M | Missense Mutation (SNP) | VAF 18/324 reads (6%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.898); called by muse, mutect2
- ZNF813 | c.548G>A p.R183K | Missense Mutation (SNP) | VAF 40/304 reads (13%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.593); called by muse, varscan2
- ZNF813 | c.632G>T p.R211I | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); called by muse, varscan2
- ABLIM2 | c.1596C>T p.P532= (on ENST00000341937 / NM_001130084.2; = p.P566= on NM_001130083.2) | Silent (SNP) | VAF 20/139 reads (14%) | catalogued as rs1214571957, COSV56410671; called by muse, mutect2, varscan2
- ACRBP | c.1626C>T p.F542= | Silent (SNP) | VAF 14/182 reads (8%) | catalogued as rs149312090, COSV57523177; called by muse, mutect2
- ADAMTS20 | c.5391T>A p.A1797= | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as COSV101239291; called by muse, mutect2
- AGL | c.1719T>A p.I573= | Silent (SNP) | VAF 44/236 reads (19%) | called by muse, mutect2, varscan2
- AKR1B15 | c.720C>T p.P240= | Silent (SNP) | VAF 30/330 reads (9%) | catalogued as rs749446377; called by muse, mutect2
- ALG10 | c.837G>A p.R279= | Silent (SNP) | VAF 15/225 reads (7%) | catalogued as rs771539230; called by muse, mutect2
- ANGPT1 | c.561C>A p.I187= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as rs1449985899, COSV99864058; called by mutect2, varscan2
- AOC3 | c.2130C>T p.F710= | Silent (SNP) | VAF 26/430 reads (6%) | catalogued as COSV57733974; called by muse, mutect2
- ARHGAP6 | c.2466C>A p.P822= (on ENST00000337414 / NM_013427.3; = p.P619= on NM_013423.3) | Silent (SNP) | VAF 10/156 reads (6%) | called by muse, mutect2
- ARSI | c.795C>A p.A265= | Silent (SNP) | VAF 61/348 reads (18%) | called by muse, mutect2, varscan2
- ATG2B | c.90G>A p.L30= | Silent (SNP) | VAF 16/195 reads (8%) | called by muse, mutect2
- ATP13A1 | c.1449G>T p.L483= | Silent (SNP) | VAF 27/426 reads (6%) | called by muse, mutect2
- C1QB | c.672C>T p.A224= | Silent (SNP) | VAF 41/200 reads (21%) | called by muse, mutect2, varscan2
- CCDC105 | c.57A>T p.P19= | Silent (SNP) | VAF 18/153 reads (12%) | called by muse, mutect2, varscan2
- CCDC40 | c.345G>T p.P115= | Silent (SNP) | VAF 65/423 reads (15%) | catalogued as COSV53896702; called by muse, mutect2, varscan2
- CD33 | c.624C>A p.T208= | Silent (SNP) | VAF 45/418 reads (11%) | called by muse, mutect2, varscan2
- CDH23 | c.1428G>T p.G476= | Silent (SNP) | VAF 80/431 reads (19%) | catalogued as rs397517306; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL1A2 | c.2502A>G p.V834= | Silent (SNP) | VAF 111/685 reads (16%) | called by muse, mutect2, varscan2
- COL21A1 | c.1656A>T p.A552= | Silent (SNP) | VAF 54/292 reads (18%) | called by muse, mutect2, varscan2
- COL6A6 | c.3918G>A p.L1306= | Silent (SNP) | VAF 14/88 reads (16%) | called by muse, mutect2, varscan2
- CYP2A7 | c.480C>T p.I160= | Silent (SNP) | VAF 38/186 reads (20%) | called by muse, varscan2
- DMXL1 | c.654A>G p.Q218= | Silent (SNP) | VAF 20/168 reads (12%) | called by muse, mutect2, varscan2
- DPP6 | c.420C>T p.D140= (on ENST00000377770 / NM_001364500.2; = p.D78= on NM_001936.5) | Silent (SNP) | VAF 28/328 reads (9%) | catalogued as rs1219071799; called by muse, mutect2
- EIF3H | c.45C>T p.S15= | Silent (SNP) | VAF 38/566 reads (7%) | catalogued as rs779097967; called by muse, mutect2
- EP400 | c.285G>T p.P95= | Silent (SNP) | VAF 40/420 reads (10%) | called by muse, mutect2
- EZH2 | c.525G>T p.V175= | Silent (SNP) | VAF 18/143 reads (13%) | called by muse, mutect2, varscan2
- FAM186B | c.2625C>T p.P875= | Silent (SNP) | VAF 35/400 reads (9%) | catalogued as rs751466311; called by muse, mutect2
- FAM81B | c.1341G>A p.V447= | Silent (SNP) | VAF 5/69 reads (7%) | called by muse, mutect2
- FBXL7 | c.1116C>A p.A372= | Silent (SNP) | VAF 46/312 reads (15%) | called by muse, mutect2, varscan2
- FSHR | c.1101C>A p.V367= | Silent (SNP) | VAF 33/419 reads (8%) | called by muse, mutect2
- GAL3ST3 | c.561C>A p.P187= | Silent (SNP) | VAF 85/280 reads (30%) | called by muse, mutect2, varscan2
- GAL3ST3 | c.396C>T p.F132= | Silent (SNP) | VAF 28/330 reads (8%) | catalogued as COSV61749774; called by muse, mutect2
- GALNTL6 | c.1053T>C p.C351= | Silent (SNP) | VAF 16/150 reads (11%) | called by mutect2, varscan2
- GRIA1 | c.970C>T p.L324= | Silent (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- GSR | c.36G>A p.A12= | Silent (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- HELZ2 | c.3630G>A p.T1210= (on ENST00000467148 / NM_001037335.2; = p.T641= on NM_033405.3) | Silent (SNP) | VAF 58/353 reads (16%) | catalogued as rs760626528, COSV64409240; called by muse, mutect2, varscan2
- HIPK2 | c.570G>A p.E190= | Silent (SNP) | VAF 89/374 reads (24%) | called by muse, mutect2, varscan2
- HNRNPH1 | c.1077C>G p.L359= | Silent (SNP) | VAF 48/344 reads (14%) | called by muse, varscan2
- HRH2 | c.216G>C p.L72= | Silent (SNP) | VAF 24/444 reads (5%) | called by muse, mutect2
- HSPA2 | c.60G>T p.G20= | Silent (SNP) | VAF 558/897 reads (62%) | called by muse, mutect2, varscan2
- IFNA8 | c.133C>A p.R45= | Silent (SNP) | VAF 46/254 reads (18%) | catalogued as rs377683966, COSV66505054; called by muse, mutect2, varscan2
- IGHV1-24 | c.189G>T p.G63= | Silent (SNP) | VAF 39/520 reads (8%) | catalogued as rs781987564; called by muse, mutect2
- IQCF1 | c.606A>T p.S202= | Silent (SNP) | VAF 19/146 reads (13%) | called by muse, mutect2, varscan2
- ITGAD | c.936G>T p.V312= | Silent (SNP) | VAF 17/189 reads (9%) | catalogued as rs780650502; called by muse, mutect2
- ITGAX | c.306T>A p.P102= | Silent (SNP) | VAF 16/72 reads (22%) | called by muse, mutect2, varscan2
- JUP | c.2127G>A p.V709= | Silent (SNP) | VAF 9/89 reads (10%) | called by muse, mutect2, varscan2
- KCNK13 | c.930C>G p.R310= | Silent (SNP) | VAF 27/334 reads (8%) | called by muse, mutect2
- KIR3DL2 | c.159T>A p.R53= | Silent (SNP) | VAF 62/424 reads (15%) | catalogued as rs773400229, COSV99552475; called by muse, mutect2, varscan2
- LMTK2 | c.3564C>G p.P1188= | Silent (SNP) | VAF 50/298 reads (17%) | called by muse, mutect2, varscan2
- MASP2 | c.645C>A p.I215= | Silent (SNP) | VAF 43/244 reads (18%) | called by muse, mutect2, varscan2
- MBTPS2 | c.1509A>T p.V503= | Silent (SNP) | VAF 31/379 reads (8%) | called by muse, mutect2
- MMP20 | c.1071C>T p.G357= | Silent (SNP) | VAF 36/600 reads (6%) | called by muse, mutect2
- MOG | c.249C>A p.G83= | Silent (SNP) | VAF 67/377 reads (18%) | called by muse, mutect2, varscan2
- MRPS26 | c.366G>T p.A122= | Silent (SNP) | VAF 51/308 reads (17%) | catalogued as COSV55662209; called by muse, mutect2, varscan2
- MUC16 | c.10680T>A p.G3560= | Silent (SNP) | VAF 33/330 reads (10%) | called by muse, mutect2, varscan2
- MUC16 | c.405C>A p.S135= | Silent (SNP) | VAF 24/415 reads (6%) | called by muse, mutect2
- MUC17 | c.8691C>T p.S2897= | Silent (SNP) | VAF 20/198 reads (10%) | called by muse, mutect2, varscan2
- MYOD1 | c.204G>T p.A68= | Silent (SNP) | VAF 51/230 reads (22%) | catalogued as rs1214841179; called by muse, mutect2, varscan2
- NANOS2 | c.216C>T p.S72= | Silent (SNP) | VAF 23/269 reads (9%) | catalogued as COSV58025255; called by muse, mutect2
- NEURL1B | c.741G>T p.P247= | Silent (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2
- NKX2-1 | c.423C>A p.G141= | Silent (SNP) | VAF 200/590 reads (34%) | catalogued as rs770003851, COSV61390233; called by muse, mutect2, varscan2
- OR11L1 | c.348C>A p.A116= | Silent (SNP) | VAF 28/326 reads (9%) | called by muse, mutect2
- OR51E1 | c.942C>T p.H314= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as rs549451979; called by muse, varscan2
- OR52A5 | c.156A>G p.K52= | Silent (SNP) | VAF 8/166 reads (5%) | called by muse, mutect2
- OR52K1 | c.327C>T p.F109= | Silent (SNP) | VAF 64/401 reads (16%) | catalogued as COSV56904433; called by muse, mutect2, varscan2
- OR5AN1 | c.279C>A p.I93= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as rs201673185; called by muse, mutect2, varscan2
- OR6K2 | c.831G>T p.L277= | Silent (SNP) | VAF 59/328 reads (18%) | called by muse, mutect2, varscan2
- PCDHA1 | c.2295C>T p.P765= | Silent (SNP) | VAF 13/198 reads (7%) | catalogued as COSV65373190; called by muse, mutect2
- PCDHA10 | c.1458C>T p.N486= | Silent (SNP) | VAF 130/480 reads (27%) | catalogued as rs1484778754, COSV56541352, COSV56553007; called by muse, mutect2, varscan2
- PDLIM7 | c.753G>T p.T251= | Silent (SNP) | VAF 19/275 reads (7%) | called by muse, mutect2
- PER2 | c.1569C>T p.T523= | Silent (SNP) | VAF 12/127 reads (9%) | called by muse, mutect2
- PHEX | c.1008C>A p.S336= | Silent (SNP) | VAF 48/490 reads (10%) | called by muse, mutect2
- PIGT | c.1305G>T p.P435= | Silent (SNP) | VAF 72/502 reads (14%) | called by muse, varscan2
- PIK3CG | c.2454C>A p.A818= | Silent (SNP) | VAF 16/168 reads (10%) | catalogued as COSV63247956; called by muse, mutect2
- PLEK | c.801C>A p.I267= | Silent (SNP) | VAF 23/191 reads (12%) | called by muse, mutect2, varscan2
- PLXNB2 | c.4875G>T p.L1625= | Silent (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
- POMC | c.156C>T p.P52= | Silent (SNP) | VAF 35/330 reads (11%) | called by muse, mutect2, varscan2
- RANBP17 | c.2748A>G p.T916= | Silent (SNP) | VAF 34/150 reads (23%) | catalogued as rs749551459; called by muse, mutect2, varscan2
- RASGRF1 | c.162C>T p.F54= | Silent (SNP) | VAF 46/370 reads (12%) | catalogued as COSV69176849; called by muse, mutect2, varscan2
- REG1A | c.306C>T p.L102= | Silent (SNP) | VAF 10/220 reads (5%) | called by muse, mutect2
- RFC4 | c.174G>T p.V58= | Silent (SNP) | VAF 30/245 reads (12%) | called by muse, mutect2, varscan2
- SATB1 | c.999G>T p.V333= | Silent (SNP) | VAF 40/504 reads (8%) | catalogued as COSV58668056; called by muse, mutect2
- SETBP1 | c.1668G>T p.L556= | Silent (SNP) | VAF 27/287 reads (9%) | called by muse, mutect2
- SGSM1 | c.2955G>T p.L985= (on ENST00000400359 / NM_001039948.4; = p.L924= on NM_133454.3) | Silent (SNP) | VAF 22/351 reads (6%) | called by muse, mutect2
- SI | c.1914G>T p.V638= | Silent (SNP) | VAF 45/271 reads (17%) | called by muse, mutect2, varscan2
- SIAH3 | c.288G>A p.G96= | Silent (SNP) | VAF 27/157 reads (17%) | called by muse, mutect2, varscan2
- SKIDA1 | c.1641C>T p.N547= | Silent (SNP) | VAF 34/179 reads (19%) | called by muse, mutect2, varscan2
- SLC18A1 | c.81A>G p.V27= | Silent (SNP) | VAF 45/248 reads (18%) | called by muse, mutect2, varscan2
- SLC25A48 | c.807T>A p.G269= (on ENST00000650267; = p.G215= on NM_001349335.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/64 reads (17%) | called by muse, mutect2
- SLC6A7 | c.1728C>T p.A576= | Silent (SNP) | VAF 63/434 reads (15%) | called by muse, mutect2, varscan2
- SLC7A14 | c.1881C>T p.Y627= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as rs1194521847; called by muse, mutect2, varscan2
- SNAI1 | c.420C>T p.A140= | Silent (SNP) | VAF 44/282 reads (16%) | called by muse, mutect2, varscan2
- ST8SIA1 | c.1068C>A p.S356= | Silent (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2, varscan2
- STAB1 | c.975C>T p.S325= | Silent (SNP) | VAF 50/343 reads (15%) | catalogued as rs1196872337; called by muse, mutect2, varscan2
- TAB2 | c.1644A>G p.Q548= | Silent (SNP) | VAF 56/310 reads (18%) | catalogued as rs777075835; called by muse, mutect2, varscan2
- TBX6 | c.1296C>T p.S432= | Silent (SNP) | VAF 11/68 reads (16%) | called by muse, mutect2, varscan2
- TMEM132E | c.1105C>A p.R369= (on ENST00000321639; = p.R459= on NM_001304438.2) | Silent (SNP) | VAF 7/138 reads (5%) | catalogued as COSV58695520; called by muse, mutect2
- TMEM145 | c.1452C>T p.L484= | Silent (SNP) | VAF 13/74 reads (18%) | called by muse, mutect2, varscan2
- TMPRSS7 | c.696G>A p.G232= | Silent (SNP) | VAF 14/142 reads (10%) | called by muse, mutect2, varscan2
- TPPP2 | c.99G>C p.L33= | Silent (SNP) | VAF 75/265 reads (28%) | called by muse, mutect2, varscan2
- TTLL4 | c.697T>C p.L233= | Silent (SNP) | VAF 16/201 reads (8%) | called by muse, mutect2
- UBN2 | c.2169G>T p.S723= | Silent (SNP) | VAF 19/182 reads (10%) | catalogued as COSV99943832; called by muse, mutect2, varscan2
- USH2A | c.12324G>T p.L4108= | Silent (SNP) | VAF 46/392 reads (12%) | called by muse, mutect2, varscan2
- ZMIZ2 | c.1587C>T p.A529= | Silent (SNP) | VAF 36/317 reads (11%) | called by muse, mutect2, varscan2
- ZNF141 | c.969C>T p.S323= | Silent (SNP) | VAF 18/264 reads (7%) | catalogued as rs1553853961; called by muse, mutect2
- ZNF805 | c.1866A>G p.P622= | Silent (SNP) | VAF 13/66 reads (20%) | called by mutect2, varscan2
- A1BG | c.*16A>T | 3'UTR (SNP) | VAF 39/444 reads (9%) | called by muse, mutect2
- AC022415.2 | c.*2862T>C | 3'UTR (SNP) | VAF 16/240 reads (7%) | called by muse, mutect2
- ACTA1 | c.*3A>G | 3'UTR (SNP) | VAF 35/492 reads (7%) | called by muse, mutect2
- ACTN2 | c.784-40del | Intron (DEL) | VAF 44/325 reads (14%) | called by mutect2, pindel, varscan2
- AGTRAP | c.62+206A>C | Intron (SNP) | VAF 35/183 reads (19%) | called by muse, mutect2, varscan2
- ALMS1P1 | n.671G>T | RNA (SNP) | VAF 31/324 reads (10%) | called by muse, mutect2
- AP000679.1 | n.289G>T | RNA (SNP) | VAF 45/157 reads (29%) | called by muse, mutect2, varscan2
- APOB | c.2436+94C>A | Intron (SNP) | VAF 26/286 reads (9%) | called by muse, mutect2
- ARHGEF4 | chr2:130914073 G>C | 5'Flank (SNP) | VAF 40/466 reads (9%) | catalogued as rs958630253; called by muse, mutect2
- ARMC2 | c.671+3638A>T | Intron (SNP) | VAF 16/105 reads (15%) | called by mutect2, varscan2
- ARNT2 | chr15:80403566 G>T | 5'Flank (SNP) | VAF 16/301 reads (5%) | catalogued as rs1325492139; called by muse, mutect2
- ASPG | c.-40G>T | 5'UTR (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2
- CA13 | c.37+589T>C | Intron (SNP) | VAF 28/371 reads (8%) | catalogued as rs769401324; called by muse, mutect2
- CBFA2T3 | c.151+25512G>C | Intron (SNP) | VAF 28/368 reads (8%) | catalogued as rs865967278, COSV51925870; called by muse, varscan2
- CD200R1 | c.451+35A>T | Intron (SNP) | VAF 13/115 reads (11%) | called by muse, mutect2, varscan2
- CDK10 | c.87+679C>T | Intron (SNP) | VAF 21/262 reads (8%) | called by muse, mutect2
- CHD3 | c.4358+213_4358+217del | Intron (DEL) | VAF 15/101 reads (15%) | called by mutect2, pindel, varscan2
- CICP28 | chr7:56811936 C>G | 3'Flank (SNP) | VAF 46/502 reads (9%) | called by muse, mutect2
- DOCK6 | c.2160+36G>T | Intron (SNP) | VAF 30/154 reads (19%) | catalogued as rs1412152805; called by muse, mutect2, varscan2
- ERCC6 | c.1397+7458C>G | Intron (SNP) | VAF 16/107 reads (15%) | called by muse, mutect2, varscan2
- FBXW9 | chr19:12688966 del C | 3'Flank (DEL) | VAF 12/121 reads (10%) | called by mutect2, pindel
- FKBP6 | c.58-38del | Intron (DEL) | VAF 42/200 reads (21%) | called by mutect2, varscan2
- FOXP2 | c.*1245G>T | 3'UTR (SNP) | VAF 17/127 reads (13%) | called by muse, mutect2, varscan2
- FXYD3 | c.-99+975A>C | Intron (SNP) | VAF 7/45 reads (16%) | catalogued as rs377515166; called by mutect2, varscan2
- GFI1 | c.*42G>C | 3'UTR (SNP) | VAF 40/337 reads (12%) | called by muse, varscan2
- GSG1L | c.551-5492C>T | Intron (SNP) | VAF 36/300 reads (12%) | called by muse, mutect2, varscan2
- GUCY2EP | n.1601G>T | RNA (SNP) | VAF 31/242 reads (13%) | called by muse, mutect2, varscan2
- HEPACAM | c.427+36C>G | Intron (SNP) | VAF 77/312 reads (25%) | called by muse, mutect2, varscan2
- KDELR1 | c.*5G>T | 3'UTR (SNP) | VAF 24/343 reads (7%) | catalogued as rs567654708; called by muse, mutect2
- KIT | c.337+44A>T | Intron (SNP) | VAF 37/298 reads (12%) | called by muse, mutect2, varscan2
- KLK11 | c.*17A>G | 3'UTR (SNP) | VAF 35/407 reads (9%) | called by muse, mutect2
- MARK3 | c.1872-10G>T | Intron (SNP) | VAF 8/136 reads (6%) | called by muse, mutect2
- MFSD13A | c.828+640G>T | Intron (SNP) | VAF 39/208 reads (19%) | called by muse, mutect2, varscan2
- MIR301B | n.40A>T | RNA (SNP) | VAF 12/190 reads (6%) | called by muse, mutect2
- MLLT6 | c.819+250A>T | Intron (SNP) | VAF 17/88 reads (19%) | called by muse, mutect2, varscan2
- NOTUM | c.473-16G>A | Intron (SNP) | VAF 15/138 reads (11%) | called by muse, mutect2, varscan2
- NRXN1 | c.3365-110027C>T | Intron (SNP) | VAF 11/64 reads (17%) | called by muse, mutect2, varscan2
- OTOGL | c.6268-289A>T | Intron (SNP) | VAF 5/95 reads (5%) | catalogued as rs1009607845; called by muse, mutect2
- PCDHB6 | chr5:141157283 C>A | 3'Flank (SNP) | VAF 53/896 reads (6%) | called by muse, mutect2
- POTED | c.*5A>T | 3'UTR (SNP) | VAF 16/54 reads (30%) | called by mutect2, varscan2
- PPDPFL | c.*673C>G | 3'UTR (SNP) | VAF 67/489 reads (14%) | called by muse, mutect2, varscan2
- PTHLH | c.524+44G>C | Intron (SNP) | VAF 20/245 reads (8%) | called by muse, mutect2
- RHAG | c.*25G>C | 3'UTR (SNP) | VAF 65/389 reads (17%) | catalogued as COSV100006485; called by muse, mutect2, varscan2
- RN7SL484P | chr15:99792060 A>T | 3'Flank (SNP) | VAF 40/260 reads (15%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159223 C>T | 5'Flank (SNP) | VAF 36/209 reads (17%) | catalogued as rs75534331; called by muse, mutect2, varscan2
- SLC6A10P | n.3121G>C | RNA (SNP) | VAF 35/260 reads (13%) | called by muse, mutect2, varscan2
- SMOX | c.1531-471A>G | Intron (SNP) | VAF 34/224 reads (15%) | called by muse, mutect2, varscan2
- SOX10 | c.-22G>A | 5'UTR (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- SOX8 | chr16:976852 G>T | 5'Flank (SNP) | VAF 46/644 reads (7%) | called by muse, mutect2
- SPATA31C2 | n.3115G>T | RNA (SNP) | VAF 68/553 reads (12%) | called by muse, mutect2, varscan2
- SPATA48 | c.652-12439C>A | Intron (SNP) | VAF 14/118 reads (12%) | called by muse, mutect2, varscan2
- STRIP2 | c.1476+89G>T | Intron (SNP) | VAF 39/168 reads (23%) | called by muse, mutect2, varscan2
- TGFBR3 | c.246+11060G>T | Intron (SNP) | VAF 11/164 reads (7%) | catalogued as rs1419870941; called by muse, mutect2
- TUBB7P | n.1169G>C | RNA (SNP) | VAF 29/354 reads (8%) | catalogued as rs781807645; called by muse, mutect2
- UQCRB | c.*2649T>G | 3'UTR (SNP) | VAF 40/158 reads (25%) | called by muse, mutect2, varscan2
- UQCRB | c.*516_*517del | 3'UTR (DEL) | VAF 14/132 reads (11%) | called by mutect2, varscan2
- Z96074.1 | n.151+3023G>A | Intron (SNP) | VAF 18/115 reads (16%) | called by muse, mutect2
- ZIC4 | c.-16+886G>T | Intron (SNP) | VAF 26/548 reads (5%) | called by muse, mutect2
- ZSWIM8 | c.*163C>G | 3'UTR (SNP) | VAF 24/306 reads (8%) | called by muse, mutect2
